Somatic mutation profile of tumor specimen 2224c03f-b7b1-4368-887e-2b4cdf (aliquot 2224c03f-b7b1-4368-887e-2b4cdf_D6_1) from CPTAC case 04OV027, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IV.
Specimen 2224c03f-b7b1-4368-887e-2b4cdf: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 667bd58d-3bd0-4cbe-99ed-8b617ad4e27d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a7f1dbca-1fbf-49a3-9ac4-6aa2f4 (Blood Derived Normal), aliquot a7f1dbca-1fbf-49a3-9ac4-6aa2f4_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69c2aff7-95c9-489e-a0e7-8f963fe2e55c

The open-access MAF lists 96 somatic variants for this specimen: 70 protein-altering or splice-affecting, 12 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 12, Intron 6, Splice Site 5, Frame Shift Del 4, Nonsense Mutation 4, 3'UTR 4, RNA 3, In Frame Del 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50461516; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 257/547 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANLN | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56077240; called by muse, mutect2, varscan2
- CHM | c.1413+1G>C p.X471_splice | Splice Site (SNP) | VAF 24/152 reads (16%) | catalogued as CS088339; called by muse, mutect2, varscan2
- PDE2A | c.2108C>A p.T703K | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57810716; called by muse, mutect2, varscan2
- PRRX2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs773930013; called by muse, mutect2, varscan2
- RBM28 | c.170A>G p.D57G | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs963927882, COSV56163086; called by muse, mutect2, varscan2
- SARDH | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as rs774102943; called by muse, mutect2, varscan2
- SLC2A11 | c.769C>A p.R257S (on ENST00000345044 / NM_001024938.4; = p.R264S on NM_030807.5) | Missense Mutation (SNP) | VAF 139/304 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as rs780794321; called by muse, mutect2, varscan2
- SLCO1B1 | c.473T>G p.V158G | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.405); catalogued as COSV57009837; called by muse, mutect2, varscan2
- TFDP1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 123/198 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64742371; called by muse, mutect2, varscan2
- TMPPE | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 107/347 reads (31%) | catalogued as COSV56563637; called by muse, mutect2, varscan2
- TRIP12 | c.3452C>G p.S1151* | Nonsense Mutation (SNP) | VAF 43/84 reads (51%) | catalogued as COSV99389715; called by muse, mutect2, varscan2
- UHRF1BP1 | c.669+1G>T p.X223_splice | Splice Site (SNP) | VAF 31/140 reads (22%) | catalogued as rs777695105, COSV99511747; called by muse, mutect2, varscan2
- UNC79 | c.7697C>G p.S2566* (on ENST00000393151 / NM_001346218.2; = p.S2389* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 20/174 reads (11%) | catalogued as COSV56375082; called by muse, mutect2, varscan2
- WDR17 | c.3443T>C p.L1148S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99708103; called by muse, mutect2, varscan2
- ZFP91 | c.858-4A>G | Splice Region (SNP) | VAF 22/145 reads (15%) | catalogued as rs768139018; called by muse, mutect2, varscan2
- ZSCAN29 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.09); catalogued as rs1413054963; called by muse, mutect2, varscan2
- AJAP1 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, varscan2
- ANKS6 | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ANKZF1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- APEX1 | c.345_364del p.H116Ffs*27 | Frame Shift Del (DEL) | VAF 81/319 reads (25%) | called by mutect2, pindel, varscan2
- BET1 | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- BRICD5 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 97/288 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- C18orf63 | c.1710A>T p.E570D | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.104); called by muse, mutect2
- CACNA2D4 | c.2300T>C p.L767P | Missense Mutation (SNP) | VAF 116/445 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CAMKK2 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCNQ | c.26G>C p.G9A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CCNQ | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CD3D | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 158/588 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH22 | c.2242A>G p.R748G | Missense Mutation (SNP) | VAF 106/265 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CFAP53 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD7 | c.8596G>T p.A2866S | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.017); called by muse, mutect2
- COL3A1 | c.3478A>G p.I1160V | Missense Mutation (SNP) | VAF 264/550 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CREB3L1 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2
- DYNC1I2 | c.754T>G p.L252V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FCRL5 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 133/403 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- FSIP2 | c.9888A>C p.K3296N | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- GSDMC | c.894A>T p.E298D | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- HIVEP3 | c.6963_6970del p.R2322Sfs*75 | Frame Shift Del (DEL) | VAF 42/136 reads (31%) | called by mutect2, pindel, varscan2
- HMGCS1 | c.1544T>G p.I515S | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- HSD17B6 | c.592G>T p.G198W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL25 | c.204C>G p.N68K | Missense Mutation (SNP) | VAF 125/355 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- JARID2 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- MAP3K1 | c.1073T>A p.L358Q | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MC4R | c.471C>G p.Y157* | Nonsense Mutation (SNP) | VAF 244/723 reads (34%) | called by muse, mutect2, varscan2
- MROH2A | c.1957T>A p.S653T | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.656); called by muse, mutect2
- MRPS21 | c.151C>G p.R51G | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.255); called by muse, mutect2
- NAV1 | c.1600A>T p.T534S | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NCBP3 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NECAP1 | c.668G>T p.S223I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR9A4 | c.451T>A p.F151I | Missense Mutation (SNP) | VAF 90/561 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ORC6 | c.634A>T p.M212L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH11X | c.3554A>G p.H1185R | Missense Mutation (SNP) | VAF 68/543 reads (13%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH8 | c.801C>G p.D267E | Missense Mutation (SNP) | VAF 92/186 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PHLDB2 | c.196G>T p.V66L | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROC | c.523_535+8del p.X175_splice | Splice Site (DEL) | VAF 20/188 reads (11%) | called by mutect2, pindel
- RNF10 | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- RNF227 | c.479_495del p.G160Afs*6 | Frame Shift Del (DEL) | VAF 16/190 reads (8%) | called by mutect2, pindel
- SCN10A | c.5299_5307del p.F1767_D1769del | In Frame Del (DEL) | VAF 69/384 reads (18%) | called by mutect2, pindel, varscan2
- SDK2 | c.6062G>T p.G2021V | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SERPIND1 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2
- SPOCK3 | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- TCERG1L | c.428C>G p.P143R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TLR7 | c.2311G>C p.V771L | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- TOM1L2 | c.1324C>G p.L442V (on ENST00000379504 / NM_001350333.2; = p.L392V on NM_001033551.3) | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM64C | c.1262_1263del p.F421* | Frame Shift Del (DEL) | VAF 61/219 reads (28%) | called by mutect2, pindel, varscan2
- TUBD1 | c.173-1G>T p.X58_splice | Splice Site (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- ZMYM4 | c.840+1G>A p.X280_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- ZNF831 | c.931_951del p.K311_R317del | In Frame Del (DEL) | VAF 70/385 reads (18%) | called by mutect2, pindel, varscan2
- CLCN5 | c.1857C>G p.G619= | Silent (SNP) | VAF 106/317 reads (33%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.2142T>A p.L714= | Silent (SNP) | VAF 54/166 reads (33%) | called by muse, mutect2, varscan2
- DISP1 | c.3009T>A p.T1003= | Silent (SNP) | VAF 34/839 reads (4%) | called by muse, mutect2
- IFFO1 | c.480G>A p.A160= | Silent (SNP) | VAF 35/94 reads (37%) | called by muse, mutect2, varscan2
- IGDCC4 | c.1287C>A p.P429= | Silent (SNP) | VAF 11/225 reads (5%) | called by muse, mutect2
- ITGAD | c.1816C>A p.R606= | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- MUC5B | c.15438C>A p.V5146= | Silent (SNP) | VAF 202/639 reads (32%) | called by muse, mutect2, varscan2
- OR13J1 | c.582C>T p.V194= | Silent (SNP) | VAF 42/846 reads (5%) | catalogued as rs1219279230; called by muse, mutect2
- RTN1 | c.1128G>A p.P376= | Silent (SNP) | VAF 81/243 reads (33%) | catalogued as rs751832060; called by muse, mutect2, varscan2
- SDK2 | c.6063C>T p.G2021= | Silent (SNP) | VAF 44/221 reads (20%) | called by muse, mutect2, varscan2
- SH2D3C | c.2358G>C p.V786= (on ENST00000314830 / NM_170600.3; = p.V629= on NM_005489.4) | Silent (SNP) | VAF 48/158 reads (30%) | called by muse, mutect2, varscan2
- SPHK2 | c.462C>A p.A154= | Silent (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- ABLIM1 | c.244+26047A>C | Intron (SNP) | VAF 28/127 reads (22%) | called by muse, mutect2, varscan2
- AC012236.1 | n.378G>T | RNA (SNP) | VAF 46/191 reads (24%) | catalogued as rs923439875; called by muse, mutect2, varscan2
- ACBD5 | chr10:27242079 C>A | 5'Flank (SNP) | VAF 41/146 reads (28%) | catalogued as rs1258352305; called by muse, mutect2, varscan2
- ATP1A3 | c.*57_*58del | 3'UTR (DEL) | VAF 23/81 reads (28%) | catalogued as rs1398939507; called by mutect2, pindel, varscan2
- CCDC74B | c.250+285_250+297del | Intron (DEL) | VAF 24/118 reads (20%) | called by mutect2, varscan2
- CSNK2B | c.72+180T>A | Intron (SNP) | VAF 125/260 reads (48%) | called by muse, mutect2, varscan2
- FAM3B | c.20-40C>A | Intron (SNP) | VAF 90/410 reads (22%) | called by muse, mutect2, varscan2
- KLC1 | c.*10611C>A | 3'UTR (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- LINC01630 | n.1264C>T | RNA (SNP) | VAF 31/79 reads (39%) | catalogued as rs561704233; called by muse, mutect2, varscan2
- NPIPP1 | n.1039C>A | RNA (SNP) | VAF 36/124 reads (29%) | called by muse, varscan2
- PLCXD2 | c.*47C>A | 3'UTR (SNP) | VAF 42/140 reads (30%) | catalogued as COSV67315581; called by muse, mutect2, varscan2
- RPSA | c.-34+256G>A | Intron (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
- SEPSECS | c.115-457C>G | Intron (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- XIAP | c.*2154C>T | 3'UTR (SNP) | VAF 39/174 reads (22%) | called by muse, mutect2, varscan2
